Somatic mutation profile of tumor specimen TCGA-AB-2859-03B (aliquot TCGA-AB-2859-03B-01W-0728-08) from TCGA case TCGA-AB-2859, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 40.2 years (14,671 days).
Specimen TCGA-AB-2859-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3380d82-a144-4581-9302-1729ff4d11a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2859-11B (Solid Tissue Normal), aliquot TCGA-AB-2859-11B-01W-0729-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e2d1d4f-5c09-40e2-81b6-600f7b7bd102

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: RNA 2, Missense Mutation 2, Silent 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GPR21 | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 17/335 reads (5%) | catalogued as COSV101016332; called by muse, mutect2
- NPM1 | c.863_864insCCTG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 9/41 reads (22%) | catalogued as rs1554138189, COSV51543231, COSV51545499, COSV51554041, COSV51557774, COSV51563665; called by mutect2, pindel, varscan2
- RARS1 | c.542A>G p.N181S | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as rs1178362012, COSV51566208; called by muse, mutect2
- VPS41 | c.758A>T p.D253V | Missense Mutation (SNP) | VAF 92/358 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV59653569; called by muse, mutect2, varscan2
- RREB1 | c.2259C>G p.T753= | Silent (SNP) | VAF 76/248 reads (31%) | catalogued as COSV58565877; called by muse, varscan2
- TFDP3 | c.1182C>T p.N394= | Silent (SNP) | VAF 399/507 reads (79%) | catalogued as rs751698892, COSV59538635; called by muse, mutect2, varscan2
- CCNQP1 | n.253G>A | RNA (SNP) | VAF 197/593 reads (33%) | catalogued as rs757134403; called by muse, mutect2, varscan2
- COL18A1-AS1 | n.1624C>T | RNA (SNP) | VAF 26/75 reads (35%) | catalogued as COSV67268836; called by muse, mutect2, varscan2
